Somatic mutation profile of tumor specimen TCGA-23-1122-01A (aliquot TCGA-23-1122-01A-01W-0486-08) from TCGA case TCGA-23-1122, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.5 years (19,537 days).
Specimen TCGA-23-1122-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48aba6fb-4413-48f4-99c8-ad440ed0f7a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1122-10A (Blood Derived Normal), aliquot TCGA-23-1122-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d6cc506-93b3-44ca-ac60-e75f7134d50a

The open-access MAF lists 158 somatic variants for this specimen: 125 protein-altering or splice-affecting, 32 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 32, Frame Shift Del 8, Nonsense Mutation 4, Splice Site 4, In Frame Del 2, Frame Shift Ins 2, Intron 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 558/642 reads (87%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA10 | c.2788C>T p.L930F | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV52226172; called by muse, mutect2, varscan2
- ABCA6 | c.812A>C p.Y271S | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52641375; called by muse, mutect2
- ABCA9 | c.2692C>T p.P898S | Missense Mutation (SNP) | VAF 459/1007 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.222); catalogued as COSV60628031; called by muse, mutect2, varscan2
- ABCC6 | c.1871C>T p.A624V | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV52745911; called by muse, mutect2, varscan2
- ADAM22 | c.1133T>C p.I378T | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV55983154; called by muse, mutect2, varscan2
- ADAM7 | c.52+1G>T p.X18_splice | Splice Site (SNP) | VAF 35/431 reads (8%) | catalogued as rs1342093322, COSV99442972; called by muse, mutect2
- ADSL | c.317T>C p.I106T | Missense Mutation (SNP) | VAF 74/583 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53408797; called by muse, mutect2, varscan2
- AGO1 | c.1252T>C p.Y418H | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64595833; called by muse, mutect2, varscan2
- ALPK1 | c.2716A>T p.T906S | Missense Mutation (SNP) | VAF 68/367 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV51588122; called by muse, mutect2, varscan2
- ANOS1 | c.1019C>A p.S340Y | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.037); catalogued as COSV99390406; called by muse, mutect2
- ARL13A | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65880277; called by muse, mutect2, varscan2
- ASIC3 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52524202; called by muse, mutect2, varscan2
- ATP6AP1 | c.1310T>C p.L437P | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63895968; called by muse, mutect2, varscan2
- AUTS2 | c.441C>G p.H147Q | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100714976; called by muse, mutect2, varscan2
- AXDND1 | c.464A>T p.Q155L | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV62645063; called by muse, mutect2, varscan2
- BBX | c.2114C>T p.P705L | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100361506, COSV57889209; called by muse, mutect2, varscan2
- BRPF3 | c.2991C>T p.G997= | Splice Region (SNP) | VAF 147/461 reads (32%) | catalogued as rs772411320, COSV60208531; called by muse, mutect2, varscan2
- CAMK2B | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV99322732; called by muse, mutect2
- CASQ1 | c.1015A>C p.I339L | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV100927232; called by muse, mutect2
- CDKAL1 | c.880A>G p.N294D | Missense Mutation (SNP) | VAF 42/583 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99214023; called by muse, mutect2
- CFAP46 | c.7325A>G p.E2442G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV99583909; called by muse, mutect2
- CHD8 | c.2408A>G p.H803R (on ENST00000646647 / NM_001170629.2; = p.H524R on NM_020920.4) | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67871680; called by muse, mutect2, varscan2
- CHRNA10 | c.1078T>C p.S360P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51705747; called by muse, mutect2, varscan2
- CLDN16 | c.512C>A p.A171D | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV53228597; called by muse, mutect2, varscan2
- CNDP2 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs559463515, COSV60840654; called by muse, mutect2, varscan2
- COL11A2 | c.2886A>T p.K962N (on ENST00000341947 / NM_080680.3; = p.K855N on NM_080679.2) | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59499515; called by muse, mutect2, varscan2
- CRTC2 | c.1876G>T p.G626C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57844123; called by muse, mutect2, varscan2
- CSMD1 | c.9579A>T p.R3193S (on ENST00000520002; = p.R3192S on NM_033225.6) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.985); catalogued as COSV59350575; called by muse, mutect2, varscan2
- CXCR4 | c.592G>C p.V198L | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV99602485; called by muse, mutect2
- CYP11B1 | c.1119G>T p.L373F | Missense Mutation (SNP) | VAF 76/623 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52828828; called by muse, mutect2, varscan2
- CYP4F2 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 55/360 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs762381741, COSV50001987; called by muse, mutect2, varscan2
- DBH | c.1000T>A p.Y334N | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99707906; called by muse, mutect2, varscan2
- DCAF4 | c.871T>A p.S291T | Missense Mutation (SNP) | VAF 114/781 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.101); catalogued as COSV62320046; called by muse, mutect2, varscan2
- DCLK2 | c.1572T>G p.C524W | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.796); catalogued as COSV56208031; called by muse, varscan2
- DDX59 | c.1142T>C p.I381T | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV58752900; called by muse, mutect2, varscan2
- DGKE | c.181G>T p.G61W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs764983358, COSV52350555; called by muse, mutect2, varscan2
- DGKH | c.2201G>C p.G734A | Missense Mutation (SNP) | VAF 66/413 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV54936316; called by muse, varscan2
- DNAH1 | c.4480G>T p.V1494F | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369984253, COSV70232214; called by muse, mutect2, varscan2
- DNAH8 | c.11634A>T p.R3878S | Missense Mutation (SNP) | VAF 93/550 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as COSV59463900; called by muse, mutect2, varscan2
- DSCAML1 | c.1163T>C p.I388T (on ENST00000321322; = p.I328T on NM_020693.4) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.547); catalogued as COSV100355205, COSV58396703; called by muse, mutect2, varscan2
- DYNC1H1 | c.11521T>C p.Y3841H | Missense Mutation (SNP) | VAF 75/136 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV64139344; called by muse, mutect2, varscan2
- EPHX1 | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 68/271 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55302264; called by muse, mutect2, varscan2
- ERMARD | c.1058T>C p.M353T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs773626265, COSV64648440; called by muse, mutect2, varscan2
- EXTL3 | c.1384G>C p.V462L | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV99593726; called by muse, mutect2
- FAM220A | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV57626905; called by muse, mutect2, varscan2
- FBH1 | c.2830G>C p.E944Q (on ENST00000362091 / NM_178150.3; = p.E995Q on NM_032807.4) | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV62983450; called by muse, mutect2, varscan2
- FCGRT | c.180C>G p.S60R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.812); catalogued as COSV55530362; called by muse, varscan2
- FOCAD | c.4106G>A p.G1369D | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs535565536, COSV58103616; called by muse, mutect2
- GHRHR | c.647A>C p.N216T | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58197270, COSV99047563; called by muse, mutect2, varscan2
- GPAM | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV62081840; called by muse, varscan2
- GUCY2C | c.1852A>G p.T618A | Missense Mutation (SNP) | VAF 168/995 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV53792652; called by muse, mutect2, varscan2
- HDAC1 | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 189/1020 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV65191596; called by muse, mutect2, varscan2
- HIC2 | c.1730C>T p.T577M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV68042532; called by muse, mutect2, varscan2
- HTR3E | c.251T>C p.L84P (on ENST00000415389 / NM_001256613.1; = p.L99P on NM_182589.2) | Missense Mutation (SNP) | VAF 172/638 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58947793; called by muse, mutect2, varscan2
- ITIH1 | c.658A>T p.T220S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV56256654; called by muse, mutect2, varscan2
- ITSN2 | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV61950657; called by muse, mutect2, varscan2
- IVD | c.128A>C p.N43T (on ENST00000651168; = p.N40T on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV51100006; called by muse, mutect2, varscan2
- KIF17 | c.1774G>T p.E592* | Nonsense Mutation (SNP) | VAF 9/111 reads (8%) | catalogued as COSV99928498; called by muse, mutect2
- KLF11 | c.62G>A p.C21Y | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.993); catalogued as COSV59940961; called by muse, mutect2, varscan2
- KMT2A | c.4391A>G p.E1464G | Missense Mutation (SNP) | VAF 65/523 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63289416; called by muse, mutect2, varscan2
- KPTN | c.1034C>G p.S345W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs763172380, COSV52641207, COSV99369904; called by muse, mutect2, varscan2
- KRTAP12-3 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs1555942976, COSV59982101; called by muse, mutect2
- LAMA2 | c.3758T>G p.L1253R | Missense Mutation (SNP) | VAF 46/550 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1510370, COSV101369994; called by muse, mutect2
- LAMB3 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs1031008727, COSV100620096; called by muse, mutect2, varscan2
- MAGI2 | c.410C>G p.T137R | Missense Mutation (SNP) | VAF 62/625 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100832741, COSV100836603; called by muse, varscan2
- MAP3K1 | c.543G>T p.E181D | Missense Mutation (SNP) | VAF 30/1012 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV68127310; called by muse, mutect2
- MRGPRX3 | c.568G>T p.V190F | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV66934315; called by muse, mutect2
- MTFMT | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1406388052, COSV54978778; called by muse, mutect2, varscan2
- MTOR | c.1109T>A p.F370Y | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV63874837; called by muse, mutect2, varscan2
- MVD | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV56331145; called by muse, mutect2, varscan2
- MYO6 | c.3868C>G p.L1290V (on ENST00000369981; = p.L1280V on NM_004999.4) | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as COSV64120088; called by muse, mutect2
- NKIRAS1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 81/465 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.086); catalogued as COSV60668775; called by muse, mutect2, varscan2
- NPC2 | c.441+2T>A p.X147_splice | Splice Site (SNP) | VAF 110/691 reads (16%) | catalogued as COSV99467037; called by muse, mutect2, varscan2
- OR5M10 | c.589A>T p.M197L | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73242376; called by muse, mutect2, varscan2
- P4HA1 | c.404T>G p.L135* | Nonsense Mutation (SNP) | VAF 22/294 reads (7%) | catalogued as COSV99696543; called by muse, mutect2
- PADI1 | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141823184; called by muse, mutect2, varscan2
- PDCD1 | c.257G>C p.R86P | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.53); catalogued as COSV57691758; called by muse, mutect2, varscan2
- PDE4A | c.1201G>A p.E401K (on ENST00000380702 / NM_001111307.2; = p.E162K on NM_006202.3) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV53359012; called by muse, mutect2, varscan2
- PGBD2 | c.853C>A p.H285N | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as COSV100251855; called by muse, mutect2
- PGLYRP1 | c.457G>C p.A153P | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.378); catalogued as COSV50517137; called by muse, mutect2, varscan2
- PHF2 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100823009; called by muse, mutect2
- POGZ | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 50/448 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778410657, COSV55038784; called by muse, mutect2, varscan2
- PRELP | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 48/512 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as rs762335688, COSV58116680; called by muse, mutect2
- RABEP1 | c.1334C>G p.A445G | Missense Mutation (SNP) | VAF 163/1191 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV52586544; called by muse, mutect2, varscan2
- RBBP4 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV100995563; called by muse, mutect2, varscan2
- RIMS4 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV65720172; called by muse, mutect2, varscan2
- RTN4R | c.644C>A p.A215D | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV50382029; called by muse, mutect2, varscan2
- S1PR1 | c.227T>A p.F76Y | Missense Mutation (SNP) | VAF 47/441 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100541470; called by muse, mutect2, varscan2
- SASS6 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99790573; called by muse, mutect2
- SCN8A | c.5215C>A p.P1739T | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61986615; called by muse, mutect2, varscan2
- SEMA3D | c.1901G>C p.R634P | Missense Mutation (SNP) | VAF 172/493 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as CM130577, COSV52398453; called by muse, mutect2, varscan2
- SERPINA5 | c.1038+1G>A p.X346_splice | Splice Site (SNP) | VAF 130/311 reads (42%) | catalogued as COSV100291458; called by muse, mutect2, varscan2
- SHANK1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99520164; called by muse, mutect2
- SMURF1 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.821); catalogued as COSV100742335; called by muse, mutect2
- SPPL3 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as COSV62233289; called by mutect2, varscan2
- TDRD1 | c.3353_3354insA p.F1118Lfs*22 | Frame Shift Ins (INS) | VAF 66/433 reads (15%) | catalogued as COSV99314039; called by mutect2, pindel, varscan2
- TIAM2 | c.82T>G p.C28G | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as rs1402890290, COSV59698258; called by muse, mutect2, varscan2
- TICRR | c.4792G>T p.E1598* | Nonsense Mutation (SNP) | VAF 35/48 reads (73%) | catalogued as COSV51544047; called by muse, mutect2, varscan2
- TMPRSS6 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100695347; called by muse, mutect2, varscan2
- TSPEAR | c.1893C>A p.S631R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV59970417; called by muse, mutect2
- TTN | c.92153C>A p.T30718N (on ENST00000591111; = p.T23294N on NM_003319.4) | Missense Mutation (SNP) | VAF 72/1598 reads (5%) | PolyPhen benign (0.001); catalogued as COSV100593750; called by muse, mutect2
- TTN | c.41144A>C p.H13715P (on ENST00000591111; = p.H6291P on NM_003319.4) | Missense Mutation (SNP) | VAF 256/1387 reads (18%) | PolyPhen probably damaging (0.997); catalogued as COSV100627197, COSV60189048; called by muse, mutect2, varscan2
- TTN | c.41075A>T p.K13692M (on ENST00000591111; = p.K6268M on NM_003319.4) | Missense Mutation (SNP) | VAF 308/1573 reads (20%) | PolyPhen benign (0.104); catalogued as COSV60189062; called by muse, mutect2, varscan2
- TTN | c.27340G>C p.A9114P (on ENST00000591111; = p.A8187P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/1236 reads (7%) | PolyPhen possibly damaging (0.563); catalogued as COSV100593759; called by muse, mutect2
- TUBGCP2 | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53306961; called by muse, varscan2
- UBL4B | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs1224595051, COSV100493989; called by muse, mutect2
- USP32 | c.3646G>T p.V1216L | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100341409; called by muse, mutect2
- ZHX3 | c.1607G>A p.R536K | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.085); catalogued as COSV100475440, COSV58384819; called by muse, mutect2
- ZNF641 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56390995; called by mutect2, varscan2
- ZNF804B | c.1155T>A p.D385E | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as rs777121427, COSV60839504; called by muse, mutect2, varscan2
- ADH6 | c.263-17_279del p.X88_splice | Splice Site (DEL) | VAF 28/154 reads (18%) | called by mutect2, pindel
- ARHGAP45 | c.3345dup p.M1116Hfs*100 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- FSCN3 | c.128G>T p.S43I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.44); called by muse, mutect2
- GRXCR1 | c.323_341del p.G108Vfs*10 | Frame Shift Del (DEL) | VAF 21/259 reads (8%) | called by mutect2, pindel
- INSYN1 | c.711del p.Y238Tfs*8 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- JAK3 | c.966_978del p.T323Ffs*2 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel
- MMP13 | c.41_45del p.W14Sfs*12 | Frame Shift Del (DEL) | VAF 47/153 reads (31%) | called by mutect2, pindel, varscan2
- MUC13 | c.433_464del p.S145Afs*25 | Frame Shift Del (DEL) | VAF 113/946 reads (12%) | called by mutect2, pindel
- NIPBL | c.8280_8312del p.P2761_I2771del | In Frame Del (DEL) | VAF 68/385 reads (18%) | called by mutect2, pindel
- RFPL4B | c.743_750del p.E248Gfs*39 | Frame Shift Del (DEL) | VAF 28/196 reads (14%) | called by mutect2, pindel, varscan2
- WDR62 | c.1557_1570del p.E520Gfs*10 | Frame Shift Del (DEL) | VAF 23/260 reads (9%) | called by mutect2, pindel
- ZIM3 | c.584_617del p.F195* | Frame Shift Del (DEL) | VAF 89/699 reads (13%) | called by mutect2, pindel
- ZNF827 | c.129_131del p.S44del | In Frame Del (DEL) | VAF 49/494 reads (10%) | called by mutect2, pindel*
- ALCAM | c.1323A>G p.P441= | Silent (SNP) | VAF 29/235 reads (12%) | catalogued as rs781540316, COSV60251281; called by muse, mutect2, varscan2
- ARAP1 | c.3096G>A p.K1032= (on ENST00000393609 / NM_001040118.2; = p.K787= on NM_015242.4) | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1333005128, COSV100501533; called by mutect2, varscan2
- CD300A | c.414G>T p.A138= | Silent (SNP) | VAF 226/1110 reads (20%) | catalogued as COSV60409917, COSV60410568; called by muse, mutect2, varscan2
- CRAT | c.477C>A p.P159= | Silent (SNP) | VAF 78/246 reads (32%) | catalogued as COSV100539780; called by muse, varscan2
- DMBT1 | c.5169C>T p.L1723= (on ENST00000338354 / NM_001377530.1; = p.L966= on NM_004406.3) | Silent (SNP) | VAF 318/809 reads (39%) | catalogued as COSV57549272, COSV57551751; called by muse, mutect2, varscan2
- DOK5 | c.198G>A p.K66= | Silent (SNP) | VAF 238/482 reads (49%) | catalogued as COSV52822666; called by muse, mutect2, varscan2
- EXOC6B | c.696C>T p.N232= | Silent (SNP) | VAF 14/220 reads (6%) | catalogued as COSV99722800; called by muse, mutect2
- GRID2 | c.891G>T p.R297= | Silent (SNP) | VAF 38/190 reads (20%) | catalogued as rs1361308965, COSV56221834, COSV56231367; called by muse, mutect2, varscan2
- IFT140 | c.1089A>C p.A363= | Silent (SNP) | VAF 48/174 reads (28%) | catalogued as COSV68491690; called by muse, varscan2
- IKBKG | c.114G>A p.E38= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV63669222; called by muse, mutect2, varscan2
- INAVA | c.813G>T p.G271= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV66257152; called by muse, mutect2, varscan2
- MAN1A2 | c.177C>T p.D59= | Silent (SNP) | VAF 34/175 reads (19%) | catalogued as COSV62979624; called by muse, mutect2, varscan2
- MYOM1 | c.4734C>G p.L1578= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV99865193; called by muse, mutect2
- MYOM2 | c.3276T>A p.I1092= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV50735262; called by muse, mutect2, varscan2
- NOX1 | c.388C>A p.R130= | Silent (SNP) | VAF 43/390 reads (11%) | catalogued as COSV54195657; called by muse, mutect2, varscan2
- PCDHA10 | c.1359G>A p.A453= | Silent (SNP) | VAF 11/12 reads (92%) | catalogued as rs372428918, COSV56494213; called by muse, mutect2, varscan2
- POPDC2 | c.117G>T p.L39= | Silent (SNP) | VAF 8/184 reads (4%) | catalogued as COSV99950820; called by muse, mutect2
- RAPSN | c.741C>T p.L247= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100100113, COSV54085111; called by muse, mutect2, varscan2
- RSPRY1 | c.1248T>A p.P416= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as COSV68028063; called by muse, mutect2, varscan2
- SCN8A | c.5535G>A p.L1845= | Silent (SNP) | VAF 74/264 reads (28%) | catalogued as COSV61986661; called by muse, mutect2, varscan2
- SHCBP1 | c.1959G>C p.G653= | Silent (SNP) | VAF 67/816 reads (8%) | catalogued as COSV57649114, COSV57649326; called by muse, mutect2
- SLC29A1 | c.1011C>T p.F337= | Silent (SNP) | VAF 13/284 reads (5%) | catalogued as COSV100505561; called by muse, mutect2
- SLITRK4 | c.105T>A p.V35= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as COSV62022008; called by muse, mutect2, varscan2
- SP140 | c.39A>G p.G13= | Silent (SNP) | VAF 43/451 reads (10%) | catalogued as rs1174913708, COSV59452348; called by muse, mutect2
- TAF8 | c.927C>T p.L309= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV65896531; called by muse, mutect2, varscan2
- TASOR2 | c.4941A>C p.T1647= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as COSV60168526; called by muse, mutect2, varscan2
- TDRD6 | c.3126C>G p.A1042= | Silent (SNP) | VAF 38/199 reads (19%) | catalogued as COSV60176960; called by muse, mutect2, varscan2
- TPTE | c.828A>G p.R276= (on ENST00000618007 / NM_199261.4; = p.R258= on NM_199259.4) | Silent (SNP) | VAF 31/855 reads (4%) | called by muse, mutect2
- TYR | c.621T>C p.F207= | Silent (SNP) | VAF 250/1557 reads (16%) | catalogued as COSV54480504; called by muse, mutect2, varscan2
- UROS | c.537C>T p.N179= | Silent (SNP) | VAF 38/557 reads (7%) | catalogued as rs762935141; called by muse, mutect2
- XPNPEP3 | c.1398G>A p.K466= | Silent (SNP) | VAF 117/314 reads (37%) | catalogued as COSV100846618; called by muse, mutect2, varscan2
- ZNF765 | c.1431G>T p.R477= | Silent (SNP) | VAF 165/623 reads (26%) | catalogued as rs535191602, COSV101125570, COSV67182943; called by muse, mutect2, varscan2
- OBSCN | c.4585+2642C>G | Intron (SNP) | VAF 14/113 reads (12%) | catalogued as COSV99472404; called by muse, mutect2, varscan2
